Somatic mutation profile of tumor specimen HCM-CSHL-0461-D12-31A (aliquot HCM-CSHL-0461-D12-31A-11D-A78U-36) from HCMI case HCM-CSHL-0461-D12, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Serrated adenoma; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage 0; Tumor grade: GX; Age at diagnosis: 54.7 years (19,976 days).
Specimen HCM-CSHL-0461-D12-31A: Sample type: Neoplasms of Uncertain and Unknown Behavior; Tissue type: Tumor; Tumor descriptor: Premalignant; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 158942ee-c191-4456-a911-df853a319680.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0461-D12-10A (Blood Derived Normal), aliquot HCM-CSHL-0461-D12-10A-01D-A78U-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ce83ad3d-86a3-46cb-8e40-a0429df3629b

The open-access MAF lists 114 somatic variants for this specimen: 82 protein-altering or splice-affecting, 29 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 65, Silent 29, Nonsense Mutation 6, Splice Region 4, Frame Shift Ins 4, Splice Site 2, Intron 2, Frame Shift Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.847C>T p.R283* | Nonsense Mutation (SNP) | VAF 142/336 reads (42%) | catalogued as rs786201856, CM920030, COSV57325157; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GNAS | c.602G>A p.R201H | Missense Mutation (SNP) | VAF 70/710 reads (10%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs121913495, CM158823, COSV55670349, COSV55671845; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- KRAS | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 52/258 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 88/359 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SMAD4 | c.692dup p.S232Qfs*3 | Frame Shift Ins (INS) | VAF 128/420 reads (30%) | catalogued as rs377767334, COSV61691229; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- SMAD4 | c.1082G>A p.R361H | Missense Mutation (SNP) | VAF 93/236 reads (39%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs377767347, CM004254, CM100519, COSV61684056, COSV61686014, COSV61689167; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADAMTSL3 | c.3415C>T p.R1139W | Missense Mutation (SNP) | VAF 82/206 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as rs145388431; called by muse, mutect2, varscan2
- APC | c.4243dup p.S1415Kfs*8 | Frame Shift Ins (INS) | VAF 67/204 reads (33%) | catalogued as COSV57328975; called by mutect2, pindel, varscan2
- BRD4 | c.977G>A p.R326Q | Missense Mutation (SNP) | VAF 32/376 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as rs781618267; called by muse, mutect2
- CHD5 | c.3191G>A p.G1064D | Missense Mutation (SNP) | VAF 10/129 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99312667; called by muse, mutect2
- CLIC1 | c.610C>T p.R204W | Missense Mutation (SNP) | VAF 20/321 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs1295329545, COSV65384150; called by muse, mutect2
- CSMD2 | c.8248G>A p.G2750S | Missense Mutation (SNP) | VAF 151/415 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.7); catalogued as rs144107939; called by muse, mutect2, varscan2
- DDRGK1 | c.917G>A p.R306Q | Missense Mutation (SNP) | VAF 23/225 reads (10%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs765906690, COSV100621416; called by muse, mutect2, varscan2
- DNAH5 | c.1852C>T p.R618* | Nonsense Mutation (SNP) | VAF 173/514 reads (34%) | catalogued as rs778780449, COSV54220884; called by muse, mutect2, varscan2
- DNAH9 | c.6526G>A p.V2176I | Missense Mutation (SNP) | VAF 30/484 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.053); catalogued as rs756835987, COSV99303286; called by muse, mutect2
- DNHD1 | c.13634C>T p.P4545L | Missense Mutation (SNP) | VAF 79/209 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV54435909; called by muse, mutect2, varscan2
- DSCAML1 | c.1642C>T p.R548W (on ENST00000321322; = p.R488W on NM_020693.4) | Missense Mutation (SNP) | VAF 51/475 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs759190973; called by muse, mutect2, varscan2
- DYNC2H1 | c.1390C>T p.R464* | Nonsense Mutation (SNP) | VAF 26/148 reads (18%) | catalogued as rs1474159674, COSV100519899; called by muse, mutect2, varscan2
- EPB41L1 | c.530C>T p.P177L | Missense Mutation (SNP) | VAF 82/722 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759662141, COSV52437690; called by muse, mutect2, varscan2
- FLG | c.1444C>A p.H482N | Missense Mutation (SNP) | VAF 222/581 reads (38%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.989); catalogued as rs745468641; called by muse, mutect2, varscan2
- FRG2C | c.821C>A p.S274* | Nonsense Mutation (SNP) | VAF 108/868 reads (12%) | catalogued as rs1392451749; called by muse, varscan2
- GRIN2A | c.2083C>T p.R695W | Missense Mutation (SNP) | VAF 175/503 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58034105; called by muse, mutect2, varscan2
- IFT88 | c.1413+12dup | Splice Region (INS) | VAF 56/166 reads (34%) | catalogued as rs769655324; called by mutect2, varscan2
- INTS6 | c.1936G>A p.G646R | Missense Mutation (SNP) | VAF 115/317 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.221); catalogued as rs1372857363, COSV60878750; called by muse, mutect2, varscan2
- LY96 | c.269G>A p.R90H | Missense Mutation (SNP) | VAF 27/255 reads (11%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.997); catalogued as rs539386615, COSV53027267; called by muse, mutect2, varscan2
- MINK1 | c.3929C>T p.S1310L | Missense Mutation (SNP) | VAF 45/135 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as rs774790111; called by muse, mutect2, varscan2
- NOL4 | c.449C>A p.A150E | Missense Mutation (SNP) | VAF 23/257 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52345895; called by muse, mutect2
- NPBWR2 | c.842T>C p.V281A | Missense Mutation (SNP) | VAF 16/234 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.349); catalogued as COSV63899936; called by muse, mutect2
- NT5C3A | c.217G>C p.G73R (on ENST00000610140 / NM_001374335.1; = p.G39R on NM_016489.13) | Missense Mutation (SNP) | VAF 132/306 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.798); catalogued as COSV54238498; called by muse, mutect2, varscan2
- PCBP1 | c.299T>G p.L100R | Missense Mutation (SNP) | VAF 24/388 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as COSV57849655, COSV57849905, COSV57849936; called by muse, mutect2
- PRDM1 | c.1553C>T p.T518M | Missense Mutation (SNP) | VAF 25/173 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); catalogued as rs753673199, COSV64845373; called by muse, mutect2, varscan2
- RAP1GDS1 | c.361C>T p.H121Y (on ENST00000408927 / NM_001100427.2; = p.H122Y on NM_021159.5) | Missense Mutation (SNP) | VAF 26/163 reads (16%) | SIFT tolerated (0.52); PolyPhen benign (0.253); catalogued as COSV99216964; called by muse, mutect2, varscan2
- ROBO2 | c.1478C>G p.S493* | Nonsense Mutation (SNP) | VAF 107/279 reads (38%) | catalogued as COSV100163019, COSV59950025; called by muse, mutect2, varscan2
- SETD1B | c.4409C>T p.T1470M | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.584); catalogued as rs1490141875; called by muse, mutect2, varscan2
- SLC32A1 | c.1321G>A p.V441I | Missense Mutation (SNP) | VAF 18/264 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.183); catalogued as rs777043497, COSV99462474; called by muse, mutect2
- SLC6A11 | c.874C>T p.R292W | Missense Mutation (SNP) | VAF 37/107 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757531916; called by muse, mutect2, varscan2
- SLFN11 | c.2195G>A p.R732H | Missense Mutation (SNP) | VAF 44/557 reads (8%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.976); catalogued as rs746690453; called by muse, mutect2
- STAG1 | c.640C>G p.Q214E | Missense Mutation (SNP) | VAF 121/299 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.596); catalogued as COSV99365835; called by muse, mutect2, varscan2
- STRC | c.502G>A p.D168N | Missense Mutation (SNP) | VAF 204/1047 reads (19%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.998); catalogued as rs1399374103; called by muse, mutect2, varscan2
- SULF1 | c.1727G>A p.R576H | Missense Mutation (SNP) | VAF 29/102 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs758690728, COSV52674097; called by muse, mutect2, varscan2
- TG | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 35/296 reads (12%) | SIFT tolerated (0.33); PolyPhen benign (0.133); catalogued as rs765016841, COSV55086355; called by muse, mutect2, varscan2
- THOC5 | c.854C>T p.T285M | Missense Mutation (SNP) | VAF 62/180 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.372); catalogued as rs141199207; called by muse, mutect2, varscan2
- TMEM108 | c.1294C>T p.R432C | Missense Mutation (SNP) | VAF 18/188 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs147035119; called by muse, mutect2
- TNFAIP8L2 | c.172C>T p.R58C | Missense Mutation (SNP) | VAF 25/212 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.516); catalogued as rs146711424; called by muse, mutect2, varscan2
- TPCN2 | c.367G>A p.G123S | Missense Mutation (SNP) | VAF 74/180 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs541105565; called by muse, mutect2, varscan2
- TRIOBP | c.7078C>T p.R2360C (on ENST00000644935 / NM_001039141.3; = p.R647C on NM_007032.5) | Missense Mutation (SNP) | VAF 53/150 reads (35%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.036); catalogued as rs371230470; called by muse, mutect2, varscan2
- UBE4B | c.2581G>A p.A861T (on ENST00000343090 / NM_001105562.3; = p.A732T on NM_006048.5) | Missense Mutation (SNP) | VAF 62/138 reads (45%) | SIFT tolerated (0.18); PolyPhen benign (0.025); catalogued as rs147329205, COSV53532772; called by muse, mutect2, varscan2
- ZFHX4 | c.1981G>T p.A661S | Missense Mutation (SNP) | VAF 22/205 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV99269376; called by muse, mutect2, varscan2
- ZNF469 | c.11483G>A p.R3828H (on ENST00000437464; = p.R3856H on NM_001367624.2) | Missense Mutation (SNP) | VAF 199/476 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as rs187075195, COSV71259370; called by muse, mutect2, varscan2
- ZNF628 | c.2726C>T p.A909V | Missense Mutation (SNP) | VAF 15/110 reads (14%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs920009714; called by muse, mutect2, varscan2
- ZNF835 | c.589G>A p.A197T | Missense Mutation (SNP) | VAF 42/442 reads (10%) | SIFT tolerated (0.34); PolyPhen benign (0.01); catalogued as COSV73379624; called by muse, mutect2
- ZNF878 | c.560G>A p.R187H | Missense Mutation (SNP) | VAF 154/482 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.03); catalogued as rs777626762, COSV72155963; called by muse, varscan2
- ANKRD33B | c.706C>T p.R236C | Missense Mutation (SNP) | VAF 37/318 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ATP2A2 | c.1037_1041del p.S346Yfs*28 | Frame Shift Del (DEL) | VAF 18/196 reads (9%) | called by mutect2, pindel
- CALB1 | c.451C>T p.L151= | Splice Region (SNP) | VAF 9/239 reads (4%) | called by muse, mutect2
- COL5A2 | c.456T>A p.P152= | Splice Region (SNP) | VAF 15/526 reads (3%) | called by muse, mutect2
- CYP4F8 | c.68T>C p.L23P | Missense Mutation (SNP) | VAF 21/348 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.062); called by muse, mutect2
- DHX38 | c.661G>A p.G221S | Missense Mutation (SNP) | VAF 16/213 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2
- EZH2 | c.2179A>G p.R727G (on ENST00000460911 / NM_001203247.2; = p.R732G on NM_004456.5) | Missense Mutation (SNP) | VAF 14/140 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- FLG | c.10183C>A p.Q3395K | Missense Mutation (SNP) | VAF 66/824 reads (8%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.974); called by muse, mutect2
- FMNL2 | c.951+5G>A | Splice Region (SNP) | VAF 48/145 reads (33%) | called by muse, mutect2, varscan2
- FOXF2 | c.574C>T p.R192W | Missense Mutation (SNP) | VAF 36/300 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GBP5 | c.118G>C p.V40L | Missense Mutation (SNP) | VAF 16/140 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.61); called by muse, mutect2, varscan2
- GPATCH8 | c.4075A>T p.I1359F | Missense Mutation (SNP) | VAF 50/423 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- ITGA7 | c.1360A>T p.K454* (on ENST00000555728; = p.K410* on NM_002206.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 103/368 reads (28%) | called by muse, mutect2, varscan2
- KRTAP9-2 | c.143G>A p.C48Y | Missense Mutation (SNP) | VAF 32/558 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.044); called by muse, mutect2
- MYO1F | c.101C>A p.A34D | Missense Mutation (SNP) | VAF 139/361 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.311); called by muse, mutect2, varscan2
- PLEKHH1 | c.2902C>A p.L968M | Missense Mutation (SNP) | VAF 6/138 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.439); called by muse, mutect2
- PPP1R7 | c.763C>T p.R255W | Missense Mutation (SNP) | VAF 69/215 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- PPP4R3C | c.281G>C p.W94S | Missense Mutation (SNP) | VAF 112/142 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PRELID3B | c.37C>G p.P13A | Missense Mutation (SNP) | VAF 54/134 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.234); called by muse, mutect2
- SIN3A | c.431A>G p.Y144C | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SMC3 | c.350+1G>C p.X117_splice | Splice Site (SNP) | VAF 76/215 reads (35%) | called by muse, mutect2, varscan2
- SOX9 | c.389dup p.L130Ffs*122 | Frame Shift Ins (INS) | VAF 20/195 reads (10%) | called by mutect2, pindel, varscan2
- TMEM200C | c.739C>G p.L247V | Missense Mutation (SNP) | VAF 22/143 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.667); called by muse, mutect2, varscan2
- TMEM87A | c.836A>T p.E279V | Missense Mutation (SNP) | VAF 86/161 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TTN | c.4370C>T p.P1457L (on ENST00000591111; = p.P1411L on NM_003319.4) | Missense Mutation (SNP) | VAF 96/275 reads (35%) | PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- UFC1 | c.256-1G>T p.X86_splice | Splice Site (SNP) | VAF 19/169 reads (11%) | called by muse, mutect2, varscan2
- UNC79 | c.4989dup p.A1664Cfs*36 (on ENST00000393151 / NM_001346218.2; = p.A1487Cfs*36 on NM_020818.5) | Frame Shift Ins (INS) | VAF 27/199 reads (14%) | called by mutect2, pindel, varscan2
- ZGRF1 | c.5272C>A p.P1758T | Missense Mutation (SNP) | VAF 83/190 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.631); called by muse, mutect2, varscan2
- ZNF423 | c.598A>G p.K200E (on ENST00000563137 / NM_001379286.1; = p.K192E on NM_015069.4) | Missense Mutation (SNP) | VAF 62/513 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF827 | c.760G>A p.A254T | Missense Mutation (SNP) | VAF 89/258 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- A2M | c.1641T>A p.P547= | Silent (SNP) | VAF 60/235 reads (26%) | called by muse, mutect2, varscan2
- ADAMTS5 | c.2343C>T p.N781= | Silent (SNP) | VAF 12/188 reads (6%) | catalogued as rs370729317; called by muse, mutect2
- ADAMTS5 | c.756G>A p.P252= | Silent (SNP) | VAF 26/237 reads (11%) | called by muse, mutect2, varscan2
- BORCS5 | c.507G>C p.L169= | Silent (SNP) | VAF 141/401 reads (35%) | called by muse, mutect2, varscan2
- CHRM3 | c.1752C>T p.R584= | Silent (SNP) | VAF 45/125 reads (36%) | catalogued as rs201601302, COSV55085033; called by muse, mutect2, varscan2
- DELE1 | c.966C>T p.C322= | Silent (SNP) | VAF 111/295 reads (38%) | called by muse, mutect2, varscan2
- DIP2A | c.4347C>T p.H1449= | Silent (SNP) | VAF 27/192 reads (14%) | catalogued as rs752202862, COSV59488667; called by muse, mutect2, varscan2
- EML6 | c.4791C>T p.P1597= | Silent (SNP) | VAF 17/217 reads (8%) | catalogued as rs766353066; called by muse, mutect2
- EPHA10 | c.1185C>T p.R395= | Silent (SNP) | VAF 29/335 reads (9%) | called by muse, mutect2
- FAT4 | c.13617C>A p.P4539= | Silent (SNP) | VAF 156/374 reads (42%) | called by muse, mutect2
- FUT8 | c.675T>C p.H225= (on ENST00000360689 / NM_001371534.1; = p.H62= on NM_004480.4) | Silent (SNP) | VAF 37/373 reads (10%) | called by muse, mutect2, varscan2
- HBG1 | c.150C>A p.S50= | Silent (SNP) | VAF 35/536 reads (7%) | catalogued as COSV100400649; called by muse, varscan2
- ITGA7 | c.1359G>T p.G453= (on ENST00000555728; = p.G409= on NM_002206.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 100/364 reads (27%) | called by muse, mutect2, varscan2
- KRT28 | c.582C>T p.N194= | Silent (SNP) | VAF 18/173 reads (10%) | catalogued as rs772215881, COSV100137681; called by muse, mutect2, varscan2
- LAMA2 | c.1188C>A p.G396= | Silent (SNP) | VAF 20/362 reads (6%) | called by muse, mutect2
- MPZ | c.651A>G p.P217= | Silent (SNP) | VAF 27/202 reads (13%) | called by muse, mutect2, varscan2
- MSR1 | c.666A>T p.V222= | Silent (SNP) | VAF 38/282 reads (13%) | called by muse, mutect2, varscan2
- MYO1B | c.541C>T p.L181= | Silent (SNP) | VAF 12/224 reads (5%) | called by muse, mutect2
- NALCN | c.3657C>T p.L1219= | Silent (SNP) | VAF 21/245 reads (9%) | catalogued as rs1566794334, COSV51929377, COSV51936438; called by muse, mutect2
- NPAP1 | c.1231C>T p.L411= | Silent (SNP) | VAF 14/284 reads (5%) | catalogued as COSV100276359; called by muse, mutect2
- PDILT | c.1323C>A p.I441= | Silent (SNP) | VAF 19/250 reads (8%) | called by muse, mutect2
- RB1CC1 | c.1677C>A p.P559= | Silent (SNP) | VAF 32/190 reads (17%) | called by muse, mutect2, varscan2
- RBM46 | c.351C>G p.A117= | Silent (SNP) | VAF 24/142 reads (17%) | called by muse, mutect2, varscan2
- RPL5 | c.114A>T p.I38= | Silent (SNP) | VAF 42/363 reads (12%) | called by muse, mutect2, varscan2
- SETBP1 | c.4164G>A p.S1388= | Silent (SNP) | VAF 119/302 reads (39%) | catalogued as rs773446890, COSV56320238; called by muse, mutect2, varscan2
- SHROOM3 | c.3210G>A p.T1070= | Silent (SNP) | VAF 116/733 reads (16%) | called by muse, mutect2, varscan2
- SLC4A9 | c.2415C>T p.F805= (on ENST00000507527 / NM_001258428.2; = p.F781= on NM_031467.3) | Silent (SNP) | VAF 10/139 reads (7%) | called by muse, mutect2
- UMAD1 | c.324C>T p.P108= | Silent (SNP) | VAF 52/438 reads (12%) | catalogued as rs533343675; called by muse, mutect2, varscan2
- ZBTB39 | c.1173C>T p.V391= | Silent (SNP) | VAF 42/333 reads (13%) | called by muse, mutect2, varscan2
- AC244517.10 | c.36-10426A>G | Intron (SNP) | VAF 72/219 reads (33%) | called by muse, mutect2, varscan2
- TCTN1 | c.*29A>T | 3'UTR (SNP) | VAF 20/192 reads (10%) | called by muse, mutect2, varscan2
- ZNF692 | c.-12-165A>G | Intron (SNP) | VAF 123/316 reads (39%) | called by muse, mutect2, varscan2
